CCDI case PBBLXS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/ff314f5e-7b3c-476e-9d7d-3b2222fc34a7

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.9 years (2,157 days).

Biospecimens (3 samples)
- Sample 0DC7SP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DC7SS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DC7T3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
